Somatic mutation profile of tumor specimen TARGET-30-PAUTVX-01A (aliquot TARGET-30-PAUTVX-01A-01D) from TARGET case TARGET-30-PAUTVX, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.9 years (1,420 days).
Specimen TARGET-30-PAUTVX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2cbcdb8-2557-4def-8b70-1db5268ee27d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUTVX-10A (Blood Derived Normal), aliquot TARGET-30-PAUTVX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea2fa4f-77c5-4d91-8067-fcc07ece2667

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.*1496C>A | 3'UTR (SNP) | VAF 28/128 reads (22%) | catalogued as COSV65959880; called by muse, mutect2, varscan2
- NPAP1 | c.*2855G>T | 3'UTR (SNP) | VAF 25/284 reads (9%) | called by muse, mutect2
